MMRF case MMRF_2503 — Multiple Myeloma CoMMpass Study (MMRF-COMMPASS)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Plasma Cell Tumors; Primary site: Hematopoietic and reticuloendothelial systems. Index date (day 0 for every day count below): first treatment.
https://portal.gdc.cancer.gov/cases/503dd7a3-4948-4510-a7c1-1e1b44099227

Demographics
Sex at birth: male; Race: white; Ethnicity: not hispanic or latino; Age at index: 67 years; Vital status: Alive.

Diagnoses (1)
1. Multiple myeloma: ICD-O-3 morphology code: 9732/3; Tissue or organ of origin: Bone marrow; Site of resection or biopsy: Bone marrow; Age at diagnosis: 67.4 years (24,601 days); ISS stage: I; Days to last known disease status: 626 days (1.7 years); Days to last follow up: 626 days (1.7 years).
   Treatment given: Therapeutic agents: Carfilzomib; Regimen or line of therapy: First line of therapy; Days to treatment start: 1 day; Days to treatment end: 2 days.
   Treatment given: Therapeutic agents: Dexamethasone; Regimen or line of therapy: First line of therapy; Days to treatment start: 1 day.
   Treatment given: Therapeutic agents: Carfilzomib; Regimen or line of therapy: First line of therapy; Days to treatment start: 3 days.

Molecular and laboratory tests (laboratory values one line per visit day; values rounded to 3 significant figures where GDC's unit conversion carried more)
- Day -12 (ECOG 1): M Protein 1.8 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 49.7 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.18 mg/dL; Immunoglobulin G 33.4 g/L; Immunoglobulin A 1.05 g/L; Immunoglobulin M 0.3 g/L; Beta 2 Microglobulin 1.8 µg/mL; Lactate Dehydrogenase 2.2 µkat/L; Hemoglobin 7.87 mmol/L; Leukocytes 5.7 ×10⁹/L; Absolute Neutrophil 3.1 ×10⁹/L; Platelets 167 ×10⁹/L; Creatinine 83.1 µmol/L; Blood Urea Nitrogen 4.64 mmol/L; Calcium 2.28 mmol/L; Albumin 40 g/L; Total Protein 8.2 g/dL; Glucose 5.94 mmol/L; C-Reactive Protein 0.039 mg/dL.
- Day 92 (ECOG 1): M Protein 0.3 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 1.44 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.1 mg/dL; Immunoglobulin G 10.5 g/L; Immunoglobulin A 0.51 g/L; Immunoglobulin M 0.25 g/L; Lactate Dehydrogenase 3.32 µkat/L; Hemoglobin 8.25 mmol/L; Leukocytes 9.5 ×10⁹/L; Absolute Neutrophil 9 ×10⁹/L; Platelets 160 ×10⁹/L; Creatinine 92.8 µmol/L; Blood Urea Nitrogen 4.28 mmol/L; Calcium 2.33 mmol/L; Albumin 44 g/L; Total Protein 6.9 g/dL; Glucose 7.92 mmol/L.
- Day 176 (ECOG 1): M Protein 0.1 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 1.31 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.17 mg/dL; Immunoglobulin G 6.67 g/L; Immunoglobulin A 0.48 g/L; Immunoglobulin M 0.21 g/L; Lactate Dehydrogenase 4.5 µkat/L; Hemoglobin 7.56 mmol/L; Leukocytes 5.1 ×10⁹/L; Absolute Neutrophil 3.7 ×10⁹/L; Platelets 132 ×10⁹/L; Creatinine 88.4 µmol/L; Blood Urea Nitrogen 3.93 mmol/L; Calcium 2.33 mmol/L; Albumin 43 g/L; Total Protein 6.3 g/dL; Glucose 5.89 mmol/L.
- Day 260 (ECOG 1): M Protein 0.05 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 1.89 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.98 mg/dL; Immunoglobulin G 6.06 g/L; Immunoglobulin A 0.93 g/L; Immunoglobulin M 0.26 g/L; Lactate Dehydrogenase 3.12 µkat/L; Hemoglobin 8.43 mmol/L; Leukocytes 4.5 ×10⁹/L; Absolute Neutrophil 2.5 ×10⁹/L; Platelets 233 ×10⁹/L; Creatinine 83.1 µmol/L; Blood Urea Nitrogen 2.86 mmol/L; Calcium 2.23 mmol/L; Albumin 40 g/L; Total Protein 6.1 g/dL; Glucose 5.17 mmol/L.
- Day 372 (ECOG 1): M Protein 0.2 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 4.18 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.53 mg/dL; Immunoglobulin G 14.7 g/L; Immunoglobulin A 2.04 g/L; Immunoglobulin M 0.3 g/L; Lactate Dehydrogenase 3.37 µkat/L; Hemoglobin 8.68 mmol/L; Leukocytes 5.9 ×10⁹/L; Absolute Neutrophil 3.1 ×10⁹/L; Platelets 225 ×10⁹/L; Creatinine 80.4 µmol/L; Blood Urea Nitrogen 4.28 mmol/L; Calcium 2.35 mmol/L; Albumin 41 g/L; Total Protein 7.1 g/dL; Glucose 4.51 mmol/L.
- Day 457 (ECOG 1): M Protein 0.2 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 3.91 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.26 mg/dL; Immunoglobulin G 12.7 g/L; Immunoglobulin A 1.91 g/L; Immunoglobulin M 1.91 g/L; Lactate Dehydrogenase 3.35 µkat/L; Hemoglobin 8.62 mmol/L; Leukocytes 5.3 ×10⁹/L; Absolute Neutrophil 3.2 ×10⁹/L; Platelets 216 ×10⁹/L; Creatinine 92.8 µmol/L; Blood Urea Nitrogen 4.28 mmol/L; Calcium 2.38 mmol/L; Albumin 41 g/L; Total Protein 6.8 g/dL; Glucose 4.84 mmol/L.
- Day 542 (ECOG 1): M Protein 0.2 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 5.02 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.16 mg/dL; Immunoglobulin G 15.3 g/L; Immunoglobulin A 2.2 g/L; Immunoglobulin M 0.35 g/L; Lactate Dehydrogenase 2.9 µkat/L; Hemoglobin 8.37 mmol/L; Leukocytes 4.8 ×10⁹/L; Absolute Neutrophil 2.7 ×10⁹/L; Platelets 209 ×10⁹/L; Creatinine 80.4 µmol/L; Blood Urea Nitrogen 3.93 mmol/L; Calcium 2.28 mmol/L; Albumin 39 g/L; Total Protein 7 g/dL; Glucose 6.22 mmol/L.
- Day 626 (ECOG 1): M Protein 0.4 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 6.73 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.46 mg/dL; Immunoglobulin G 14.6 g/L; Immunoglobulin A 2.2 g/L; Immunoglobulin M 0.46 g/L; Lactate Dehydrogenase 2.43 µkat/L; Hemoglobin 8.56 mmol/L; Leukocytes 5 ×10⁹/L; Absolute Neutrophil 2.6 ×10⁹/L; Platelets 217 ×10⁹/L; Creatinine 87.5 µmol/L; Blood Urea Nitrogen 4.64 mmol/L; Calcium 2.25 mmol/L; Albumin 37 g/L; Total Protein 6.8 g/dL; Glucose 6.11 mmol/L.

Other clinical attributes
- Day -12: Weight: 105 kg; Height: 180 cm.

Family history
- Relative with cancer history: yes; Relationship type: Father; Relationship sex at birth: male.
- Relative with cancer history: yes; Relationship type: Child.

Biospecimens (2 samples)
- Sample MMRF_2503_1_BM_CD138pos: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS; Days to sample procurement: -12 days.
- Sample MMRF_2503_1_PB_Whole: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS; Days to sample procurement: -12 days.
